Somatic mutation profile of tumor specimen C3N-00847-01 (aliquot CPT0027650009) from CPTAC case C3N-00847, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 65.0 years (23,757 days).
Specimen C3N-00847-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd464555-25a7-44c4-addb-e0e6be0f7469.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00847-71 (Blood Derived Normal), aliquot CPT0027740002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8d1e736-7f67-4890-9269-a39701470f6a

The open-access MAF lists 84 somatic variants for this specimen: 57 protein-altering or splice-affecting, 19 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 19, Frame Shift Del 4, Nonsense Mutation 4, Intron 3, In Frame Del 2, 5'UTR 2, 5'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYFIP2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs1131692231, COSV59037367; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- JAG1 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 34/302 reads (11%) | catalogued as rs886043606, CM061812, COSV99652558; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6981G>A p.M2327I | Missense Mutation (SNP) | VAF 6/120 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs878855328, COSV63868602, COSV63869693, COSV63874461; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 151/422 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.130A>G p.N44D | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774528779; called by muse, mutect2, varscan2
- ABLIM2 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs760144899, COSV99590176; called by muse, mutect2
- ANKRD18A | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1055445995, COSV68804917; called by muse, mutect2
- ARHGAP6 | c.2358C>G p.S786R (on ENST00000337414 / NM_013427.3; = p.S583R on NM_013423.3) | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.153); catalogued as COSV57298313; called by muse, mutect2, varscan2
- CACNA1F | c.3511C>T p.R1171C | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs376061476; called by muse, mutect2
- CDH20 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.053); catalogued as rs542150773, COSV99406409; called by muse, mutect2, varscan2
- COL14A1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs771290485, COSV52850061; called by muse, mutect2, varscan2
- CTCF | c.1568dup p.Y523* | Nonsense Mutation (INS) | VAF 60/176 reads (34%) | catalogued as COSV99081339; called by mutect2, pindel, varscan2
- DCAF8L2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1292398178; called by muse, mutect2, varscan2
- ECH1 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757944285; called by muse, mutect2, varscan2
- EMID1 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs377281956; called by muse, mutect2
- FOCAD | c.4832G>A p.R1611H | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs750541536, COSV58102064; called by muse, mutect2, varscan2
- HINT3 | c.497A>G p.N166S | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs577650419; called by muse, mutect2, varscan2
- JUP | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs369486398, CM1313056; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT37 | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs141724873; called by muse, mutect2, varscan2
- KRT6B | c.1058A>T p.E353V | Missense Mutation (SNP) | VAF 211/574 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52883650; called by muse, mutect2, varscan2
- LRRC7 | c.2533C>T p.R845C (on ENST00000651989 / NM_001370785.2; = p.R812C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1182861744, COSV50414820; called by muse, mutect2, varscan2
- MBD1 | c.1123C>T p.R375C (on ENST00000269468 / NM_001323950.1; = p.R352C on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 159/405 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54000042; called by muse, mutect2, varscan2
- NEURL4 | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs200726218; called by muse, mutect2, varscan2
- OR10A7 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 99/253 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.177); catalogued as COSV58279722; called by muse, mutect2, varscan2
- OR6A2 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 95/229 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs778988808, COSV100215782, COSV60264834; called by muse, mutect2, varscan2
- PCDHA5 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 209/589 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.15); catalogued as COSV100972067; called by muse, mutect2, varscan2
- PCDHGA8 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 110/277 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV53949255; called by muse, mutect2, varscan2
- PLCG2 | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); catalogued as rs1216454496, COSV100842693, COSV63875044; called by muse, mutect2, varscan2
- POTEE | c.683A>G p.H228R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.451); catalogued as rs1227400348; called by mutect2, varscan2
- RASA1 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs746430799, COSV57195210; called by muse, mutect2
- SCARA5 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1391194257, COSV100107669; called by muse, mutect2, varscan2
- SDCBP2 | c.347G>A p.R116H (on ENST00000339987 / NM_001199784.1; = p.R31H on NM_015685.5) | Missense Mutation (SNP) | VAF 114/242 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV60588974; called by muse, mutect2, varscan2
- SDK2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.378); catalogued as rs574582614, COSV66187387; called by muse, mutect2, varscan2
- SURF6 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 120/379 reads (32%) | catalogued as rs781994914; called by muse, mutect2, varscan2
- TCF15 | c.548del p.G183Afs*4 | Frame Shift Del (DEL) | VAF 57/143 reads (40%) | catalogued as rs998181354; called by mutect2, pindel, varscan2
- TNFSF11 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs150392469; called by muse, mutect2, varscan2
- USP43 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.487); catalogued as rs200060469, COSV99557016; called by muse, mutect2, varscan2
- VSTM2L | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs377435668; called by muse, mutect2
- AC093827.5 | c.330G>C p.L110F | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- AIMP1 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 88/257 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AMIGO2 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.743_753del p.G248Afs*148 | Frame Shift Del (DEL) | VAF 22/27 reads (81%) | called by mutect2, varscan2
- CNOT9 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNNB1 | c.95_97del p.D32_S33delinsA | In Frame Del (DEL) | VAF 118/312 reads (38%) | called by mutect2, pindel, varscan2
- DLST | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- GSK3A | c.686_695del p.F229Wfs*116 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- HMCN1 | c.4224G>C p.Q1408H | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.83); called by muse, mutect2
- KIF4A | c.1872A>C p.K624N | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO1D | c.1328A>T p.D443V | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NR1D1 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDZD4 | c.666G>A p.W222* | Nonsense Mutation (SNP) | VAF 48/131 reads (37%) | called by muse, mutect2, varscan2
- PITPNM1 | c.3725G>C p.S1242T | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.009); called by muse, mutect2
- PRRC2C | c.1591_1593del p.K531del (on ENST00000367742; = p.K529del on NM_015172.4) | In Frame Del (DEL) | VAF 32/225 reads (14%) | called by mutect2, pindel, varscan2
- RSBN1 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RTN4R | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SPATA31A1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 48/442 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.111); called by muse, mutect2
- ZYG11B | c.2220del p.A741Pfs*3 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, varscan2
- ALDH18A1 | c.1485C>T p.I495= | Silent (SNP) | VAF 166/421 reads (39%) | catalogued as rs777125038, COSV64662087; called by muse, mutect2, varscan2
- C2CD3 | c.144C>T p.V48= | Silent (SNP) | VAF 31/368 reads (8%) | called by muse, mutect2
- DNAH10 | c.11715C>T p.A3905= (on ENST00000409039; = p.A3844= on NM_207437.3) | Silent (SNP) | VAF 74/181 reads (41%) | catalogued as rs768774769, COSV68987633; called by muse, mutect2, varscan2
- GATA4 | c.201G>A p.S67= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as rs1296081004; called by muse, mutect2, varscan2
- GPR101 | c.165G>T p.V55= | Silent (SNP) | VAF 38/90 reads (42%) | called by muse, mutect2, varscan2
- GTF3C1 | c.855G>A p.L285= | Silent (SNP) | VAF 79/281 reads (28%) | called by muse, mutect2, varscan2
- HMCN1 | c.4113G>A p.S1371= | Silent (SNP) | VAF 115/335 reads (34%) | catalogued as rs146606430; called by muse, mutect2, varscan2
- INTS1 | c.2868C>T p.D956= | Silent (SNP) | VAF 56/163 reads (34%) | catalogued as rs1367673450; called by muse, mutect2, varscan2
- LGI2 | c.234C>T p.D78= | Silent (SNP) | VAF 92/235 reads (39%) | called by muse, mutect2, varscan2
- MDN1 | c.14328G>A p.E4776= | Silent (SNP) | VAF 11/261 reads (4%) | called by muse, mutect2
- NOMO1 | c.2142C>T p.I714= | Silent (SNP) | VAF 47/712 reads (7%) | catalogued as rs763611245, COSV55061141; called by muse, mutect2
- NSMCE3 | c.168C>T p.G56= | Silent (SNP) | VAF 64/152 reads (42%) | called by muse, mutect2, varscan2
- ONECUT3 | c.459G>A p.P153= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2
- PCDHA12 | c.2037G>A p.S679= | Silent (SNP) | VAF 50/367 reads (14%) | catalogued as rs781824762; called by muse, mutect2, varscan2
- PCDHA4 | c.1671C>T p.D557= | Silent (SNP) | VAF 226/543 reads (42%) | catalogued as rs1451689285, COSV63545662; called by muse, mutect2, varscan2
- RPS6KB2 | c.246C>T p.F82= | Silent (SNP) | VAF 9/163 reads (6%) | catalogued as rs1414517205; called by muse, mutect2
- TTC12 | c.1167G>A p.A389= | Silent (SNP) | VAF 74/196 reads (38%) | catalogued as rs1465356557, COSV59096643; called by muse, mutect2, varscan2
- VPS26C | c.684C>T p.D228= | Silent (SNP) | VAF 56/137 reads (41%) | catalogued as rs374517236; called by muse, mutect2, varscan2
- XPNPEP1 | c.1299C>T p.N433= | Silent (SNP) | VAF 75/238 reads (32%) | catalogued as rs376317884; called by muse, mutect2, varscan2
- AC139769.1 | n.214-4287A>G | Intron (SNP) | VAF 117/294 reads (40%) | called by muse, mutect2, varscan2
- DPP6 | c.-2C>T | 5'UTR (SNP) | VAF 55/281 reads (20%) | called by muse, mutect2, varscan2
- EIF2AK1 | c.118+785C>T | Intron (SNP) | VAF 37/141 reads (26%) | catalogued as rs767815092; called by muse, mutect2, varscan2
- MPDU1 | chr17:7583801 C>T | 5'Flank (SNP) | VAF 160/432 reads (37%) | catalogued as rs1293469889; called by muse, mutect2, varscan2
- PTGES3L | c.*11C>T | 3'UTR (SNP) | VAF 14/109 reads (13%) | catalogued as rs763075866; called by muse, mutect2, varscan2
- RHBDL1 | chr16:675779 C>T | 5'Flank (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- STIM1 | c.1474+1246C>T | Intron (SNP) | VAF 79/246 reads (32%) | called by muse, mutect2, varscan2
- XK | c.-6G>A | 5'UTR (SNP) | VAF 61/185 reads (33%) | called by muse, mutect2, varscan2
